HCMI case HCM-CSHL-1269-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2b7832fe-682f-4bca-97ec-5f7bf6070e5f

Demographics
Sex at birth: female; Year of birth: 1967; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.6; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 49.4 years (18,035 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Liver.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 26 days; Days to treatment end: 209 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 26 days; Days to treatment end: 209 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 209 days; Days to treatment end: 786 days (2.2 years).
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 421 days (1.2 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 817 days (2.2 years); Days to treatment end: 939 days (2.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 817 days (2.2 years); Days to treatment end: 939 days (2.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 939 days (2.6 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 1,250 days (3.4 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,275 days (3.5 years); Days to treatment end: 1,442 days (3.9 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,442 days (3.9 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 1,442 days (3.9 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 1,711 days (4.7 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 49.4 years (18,035 days).
   Pathology details: Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 1,711 days (4.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 1,598.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CEA: 9.33 ng/mL.
- KRAS mutation, nos: Positive; Amino-acid change: p.Gln61His.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.
- Test (Microsatellite Analysis): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 155 cm; BMI: 27.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-1269-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-1269-C18-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 87; Percent normal cells: 9; Percent necrosis: 14; Percent stromal cells: 17; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-1269-C18-06A-01-S1-HE: Section location: Top; Percent tumor cells: 57; Percent tumor nuclei: 82; Percent normal cells: 12; Percent necrosis: 17; Percent stromal cells: 14; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-1269-C18-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-1269-C18-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-1269-C18-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-1269-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
